CPTAC case C3L-02553 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/12ad98c8-dace-4d24-a529-224efbe3a419

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1960; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 57.3 years (20,920 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,793 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,793 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm (a second GDC size field records 3.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 320 days; Disease response: Tumor Free.
- Days to follow up: 701 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,066 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,433 days (3.9 years); Disease response: Complete Response.
- Days to follow up: 1,433 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,793 days (4.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 88 kg; Height: 175 cm; BMI: 28.73.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 54; Cigarettes per day: 40; Tobacco smoking onset year: 1976; Tobacco smoking quit year: 2003; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 27; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02553-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 208 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02553-21: Section location: Lower pole; Percent tumor nuclei: 95; Percent necrosis: 0.
- Sample C3L-02553-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
